Gene-level copy-number profile of tumor specimen TCGA-14-0736-01A from TCGA case TCGA-14-0736, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.9 years (18,219 days).
Specimen TCGA-14-0736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.47c84fd6-9daf-448b-9adc-94fa4bb3b9ac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-0736-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/01a8e35c-6126-4720-ae0f-5c923d70fe16

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 26; copy number 2: 19,051; copy number 3: 912; copy number 4: 38,134; copy number 5: 368; copy number 6: 562; copy number 7: 69; copy number 8: 69; copy number 10: 23; copy number 11: 22; copy number 19: 335; copy number 20: 7; copy number 21: 32; copy number 22: 8; copy number 23: 13; copy number 25: 170; copy number 32: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-0736-01A-01D-0517-01): tumor purity 0.57, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:13,264,861–13,487,662, 4 genes (within-gene range 0–2): AL008729.1, TBC1D7, AL008729.2, GFOD1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 620 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:10,449,820–10,779,944, 1 gene, copy number 23 (within-gene range 7–23): MGC4859.
- chr7:10,702,676–14,071,380, 33 genes, copy number 11–23: AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21.
- chr7:16,791,811–16,833,433, 1 gene, copy number 23 (within-gene range 6–23): AGR2.
- chr7:16,859,412–17,467,256, 11 genes, copy number 10–22 (within-gene range 6–22): AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2.
- chr7:23,105,758–23,177,914, 1 gene, copy number 20 (within-gene range 6–20): KLHL7.
- chr7:23,181,841–23,311,729, 5 genes, copy number 20: NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1.
- chr7:26,152,198–29,195,451, 85 genes, copy number 25 (within-gene range 6–25) (broad region; genes not listed).
- chr7:30,852,273–37,449,249, 105 genes, copy number 10–25 (within-gene range 6–25) (broad region; genes not listed).
- chr7:50,093,279–50,094,123, 1 gene, copy number 20: AC034148.1.
- chr7:51,614,251–67,362,950, 377 genes, copy number 19–32 (within-gene range 3–32) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
